Somatic mutation profile of tumor specimen 0DIDTV from CCDI case PBBVNV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Choroid plexus papilloma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.7 years (609 days).
Specimen 0DIDTV: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 543b219f-3b3e-43ad-80d2-f0d803f15d79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIDS4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b488b142-85fc-4dbd-9c3a-77416d3608ff

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.2131G>A p.V711I | Missense Mutation (SNP) | VAF 270/698 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.125); catalogued as COSV104389399; called by muse, mutect2
- RBM15B | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.84); called by muse, mutect2
